Somatic mutation profile of tumor specimen C3N-03791-02 (aliquot CPT0248160007) from CPTAC case C3N-03791, project CPTAC-3 (Brain — Gliomas). Sex at birth: female; Vital status: Dead; Primary diagnosis: Glioblastoma; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 63.9 years (23,354 days).
Specimen C3N-03791-02: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Brain; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) b49d7ed3-aa4f-4bfc-b5cb-1daf41b5ac65.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen C3N-03791-31 (Blood Derived Normal), aliquot CPT0248220002; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/a289e4a5-39c6-4808-8247-bf5298a9b896

The open-access MAF lists 71 somatic variants for this specimen: 51 protein-altering or splice-affecting, 13 silent, 7 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 41, Silent 13, Nonsense Mutation 5, RNA 5, Frame Shift Del 3, Intron 2, Splice Site 1, Splice Region 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- PTEN | c.1027-1G>T p.X343_splice | Splice Site (SNP) | VAF 130/312 reads (42%) | hotspot (GDC flag); catalogued as CS1413088, COSV64290834, COSV64293694, COSV64298429; called by muse, mutect2, varscan2
- TP53 | c.646G>A p.V216M | Missense Mutation (SNP) | VAF 117/353 reads (33%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs730882025, CM159291, CX952222, COSV52671096, COSV52751864, COSV53384298; ClinVar: uncertain significance / likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- ABCB1 | c.2245C>T p.R749* | Nonsense Mutation (SNP) | VAF 57/296 reads (19%) | catalogued as rs1323297861, COSV55948448; called by muse, mutect2, varscan2
- ARSH | c.1177G>A p.G393R | Missense Mutation (SNP) | VAF 60/183 reads (33%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.875); catalogued as rs145391454, COSV101139759; called by muse, mutect2, varscan2
- CCDC150 | c.2479C>T p.R827C | Missense Mutation (SNP) | VAF 12/158 reads (8%) | SIFT deleterious (0); PolyPhen possibly damaging (0.855); catalogued as rs752923027, COSV55876484; called by muse, mutect2
- CFTR | c.2521C>G p.P841A | Missense Mutation (SNP) | VAF 40/297 reads (13%) | SIFT tolerated (0.99); PolyPhen benign (0.156); catalogued as COSV50066153; called by muse, mutect2, varscan2
- COL2A1 | c.613C>T p.P205S | Missense Mutation (SNP) | VAF 100/311 reads (32%) | SIFT tolerated (0.16); PolyPhen probably damaging (0.998); catalogued as COSV61528000; called by muse, mutect2, varscan2
- COQ2 | c.1081G>T p.G361* | Nonsense Mutation (SNP) | VAF 82/288 reads (28%) | catalogued as COSV61021714; called by muse, mutect2, varscan2
- DIRAS2 | c.422G>A p.R141H | Missense Mutation (SNP) | VAF 11/309 reads (4%) | SIFT tolerated (0.08); PolyPhen benign (0.229); catalogued as COSV101005849; called by muse, mutect2
- EIF4A2 | c.5C>T p.S2F | Missense Mutation (SNP) | VAF 76/342 reads (22%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.828); catalogued as rs764605841, COSV100125656, COSV60624675; called by muse, mutect2, varscan2
- FAT2 | c.9497C>T p.T3166M | Missense Mutation (SNP) | VAF 97/360 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.976); catalogued as rs148189364; called by muse, mutect2, varscan2
- FFAR3 | c.617G>A p.R206H | Missense Mutation (SNP) | VAF 110/464 reads (24%) | SIFT tolerated (0.2); PolyPhen benign (0.039); catalogued as rs141691304, COSV59909014; called by muse, mutect2, varscan2
- IGFBP4 | c.529G>A p.E177K | Missense Mutation (SNP) | VAF 43/215 reads (20%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.978); catalogued as rs1167453383, COSV54096634; called by muse, mutect2, varscan2
- IL36G | c.362G>A p.R121H | Missense Mutation (SNP) | VAF 80/296 reads (27%) | SIFT tolerated (1); PolyPhen benign (0.009); catalogued as rs780697688, COSV52077685; called by muse, mutect2, varscan2
- KRT3 | c.997G>A p.D333N | Missense Mutation (SNP) | VAF 38/184 reads (21%) | SIFT tolerated (1); PolyPhen benign (0.013); catalogued as rs754692663, COSV58815054; called by muse, mutect2, varscan2
- LRP12 | c.647C>A p.A216D | Missense Mutation (SNP) | VAF 14/182 reads (8%) | SIFT tolerated (0.16); PolyPhen benign (0.091); catalogued as COSV52628769; called by muse, mutect2
- OR6C6 | c.364G>A p.V122I | Missense Mutation (SNP) | VAF 37/132 reads (28%) | SIFT tolerated, low confidence (0.11); PolyPhen benign (0.009); catalogued as rs201844969; called by muse, mutect2, varscan2
- OR7A10 | c.205G>A p.V69I | Missense Mutation (SNP) | VAF 54/171 reads (32%) | SIFT deleterious, low confidence (0.05); PolyPhen benign (0.237); catalogued as rs774022847, COSV50166245; called by muse, mutect2, varscan2
- PLCL1 | c.671G>A p.R224Q | Missense Mutation (SNP) | VAF 36/242 reads (15%) | SIFT tolerated (0.17); PolyPhen benign (0.125); catalogued as rs61752177, COSV70821156; called by muse, mutect2, varscan2
- PRAMEF11 | c.442C>T p.P148S | Missense Mutation (SNP) | VAF 182/793 reads (23%) | SIFT deleterious (0.02); PolyPhen benign (0.131); catalogued as rs559323409; called by muse, mutect2
- RBM33 | c.1057C>A p.P353T | Missense Mutation (SNP) | VAF 12/172 reads (7%) | SIFT tolerated (0.46); PolyPhen benign (0.154); catalogued as COSV56634427; called by muse, mutect2
- SDK1 | c.3685G>A p.V1229I | Missense Mutation (SNP) | VAF 30/775 reads (4%) | SIFT tolerated (1); PolyPhen benign (0.007); catalogued as rs146383881; called by muse, mutect2
- TGFB1 | c.601A>G p.T201A | Missense Mutation (SNP) | VAF 108/433 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV55726399; called by muse, mutect2, varscan2
- TNFSF15 | c.392G>A p.R131Q | Missense Mutation (SNP) | VAF 35/212 reads (17%) | SIFT tolerated (0.36); PolyPhen benign (0.026); catalogued as rs370931148; called by muse, mutect2, varscan2
- TRPV4 | c.1336C>T p.R446C | Missense Mutation (SNP) | VAF 87/335 reads (26%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.939); catalogued as rs145900289; called by muse, mutect2, varscan2
- TTC27 | c.1409A>G p.E470G | Missense Mutation (SNP) | VAF 64/254 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs141709300; called by muse, mutect2, varscan2
- WNK2 | c.3563G>A p.R1188Q | Missense Mutation (SNP) | VAF 17/54 reads (31%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.978); catalogued as rs571774775, COSV52942140; called by muse, mutect2, varscan2
- XIRP2 | c.4695_4696del p.G1566Kfs*26 (on ENST00000628543; = p.G1741Kfs*26 on NM_152381.6) | Frame Shift Del (DEL) | VAF 32/279 reads (11%) | catalogued as rs1476739389; called by pindel, varscan2
- AC097636.1 | c.183G>A p.W61* | Nonsense Mutation (SNP) | VAF 57/186 reads (31%) | called by muse, mutect2, varscan2
- AKAP13 | c.4954G>T p.E1652* (on ENST00000394518 / NM_007200.5; = p.E1656* on NM_006738.6) | Nonsense Mutation (SNP) | VAF 38/134 reads (28%) | called by muse, mutect2, varscan2
- ANLN | c.58del p.Q20Rfs*15 | Frame Shift Del (DEL) | VAF 18/112 reads (16%) | called by mutect2, pindel, varscan2
- C20orf27 | c.116C>A p.S39* (on ENST00000379772 / NM_001258429.2; = p.S64* on NM_001039140.3) | Nonsense Mutation (SNP) | VAF 73/254 reads (29%) | called by muse, mutect2, varscan2
- DNAJC10 | c.1576A>G p.T526A | Missense Mutation (SNP) | VAF 14/173 reads (8%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.983); called by muse, mutect2
- DSG4 | c.1531G>C p.V511L | Missense Mutation (SNP) | VAF 83/344 reads (24%) | SIFT deleterious (0); PolyPhen benign (0.291); called by muse, mutect2, varscan2
- DYNC2H1 | c.9253G>A p.A3085T | Missense Mutation (SNP) | VAF 104/305 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- FAT3 | c.4084T>C p.F1362L | Missense Mutation (SNP) | VAF 38/243 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- FGGY | c.1150G>T p.V384F | Missense Mutation (SNP) | VAF 59/261 reads (23%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.516); called by muse, mutect2, varscan2
- HNRNPCL1 | c.368T>G p.M123R | Missense Mutation (SNP) | VAF 99/344 reads (29%) | SIFT tolerated (0.06); PolyPhen benign (0.24); called by muse, mutect2, varscan2
- NAP1L3 | c.383C>A p.A128E | Missense Mutation (SNP) | VAF 12/152 reads (8%) | SIFT tolerated (1); PolyPhen benign (0.286); called by muse, mutect2
- NCOA2 | c.226del p.T76Lfs*2 | Frame Shift Del (DEL) | VAF 28/99 reads (28%) | called by mutect2, pindel, varscan2
- OR52R1 | c.912C>G p.D304E | Missense Mutation (SNP) | VAF 15/63 reads (24%) | SIFT tolerated (0.43); PolyPhen benign (0.007); called by muse, varscan2
- PCDHB3 | c.1720G>A p.E574K | Missense Mutation (SNP) | VAF 247/816 reads (30%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.969); called by muse, mutect2, varscan2
- PIGO | c.2834C>G p.A945G | Missense Mutation (SNP) | VAF 26/146 reads (18%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.837); called by muse, varscan2
- PRMT9 | c.1346C>T p.P449L | Missense Mutation (SNP) | VAF 29/110 reads (26%) | SIFT tolerated (0.06); PolyPhen benign (0); called by muse, mutect2, varscan2
- RNF213 | c.4527+7C>T | Splice Region (SNP) | VAF 22/238 reads (9%) | called by muse, mutect2
- SOWAHD | c.598G>A p.D200N | Missense Mutation (SNP) | VAF 77/280 reads (28%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.639); called by muse, mutect2, varscan2
- SUOX | c.1565T>A p.V522E | Missense Mutation (SNP) | VAF 89/331 reads (27%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.526); called by muse, mutect2, varscan2
- TTN | c.31882A>G p.K10628E (on ENST00000591111; = p.K9701E on NM_133378.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 25/85 reads (29%) | PolyPhen benign (0.015); called by muse, mutect2
- TUBB2B | c.142A>T p.N48Y | Missense Mutation (SNP) | VAF 75/246 reads (30%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.103); called by muse, mutect2, varscan2
- TUBB4A | c.689C>T p.S230L | Missense Mutation (SNP) | VAF 196/620 reads (32%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.915); called by muse, mutect2, varscan2
- ZFP92 | c.581C>T p.A194V | Missense Mutation (SNP) | VAF 18/181 reads (10%) | SIFT tolerated (0.08); PolyPhen benign (0.37); called by muse, mutect2
- ADAMTSL5 | c.420C>T p.F140= | Silent (SNP) | VAF 15/292 reads (5%) | called by muse, mutect2
- BCORL1 | c.2151C>T p.Y717= | Silent (SNP) | VAF 47/192 reads (24%) | catalogued as rs749178911, COSV54389180; called by muse, mutect2, varscan2
- CD81 | c.426C>T p.N142= | Silent (SNP) | VAF 72/419 reads (17%) | catalogued as rs369472934; called by muse, mutect2, varscan2
- CELF4 | c.927C>T p.A309= | Silent (SNP) | VAF 33/154 reads (21%) | catalogued as rs368233040; called by muse, mutect2, varscan2
- CRTAP | c.288C>T p.P96= | Silent (SNP) | VAF 38/271 reads (14%) | called by muse, mutect2, varscan2
- FBLN2 | c.2811C>T p.D937= | Silent (SNP) | VAF 116/466 reads (25%) | catalogued as rs553735734, COSV99851441; called by muse, mutect2, varscan2
- MAOB | c.1200T>A p.T400= | Silent (SNP) | VAF 56/194 reads (29%) | catalogued as COSV65206941; called by muse, mutect2, varscan2
- MYO3A | c.4389G>A p.S1463= | Silent (SNP) | VAF 90/238 reads (38%) | catalogued as rs765271639, COSV56337319; called by muse, mutect2, varscan2
- MYOM1 | c.3498G>A p.K1166= | Silent (SNP) | VAF 8/124 reads (6%) | called by muse, mutect2
- PF4V1 | c.93C>T p.F31= | Silent (SNP) | VAF 25/226 reads (11%) | catalogued as COSV99896297; called by muse, mutect2, varscan2
- POTEF | c.2448C>T p.R816= | Silent (SNP) | VAF 92/699 reads (13%) | catalogued as rs562326654, COSV100665255, COSV62545450; called by muse, mutect2, varscan2
- RNF223 | c.75C>T p.P25= | Silent (SNP) | VAF 32/107 reads (30%) | called by muse, mutect2, varscan2
- UMODL1 | c.1236G>A p.T412= | Silent (SNP) | VAF 7/96 reads (7%) | catalogued as rs1003035471, COSV61159637, COSV61161434; called by muse, mutect2
- ABCB1 | c.1350+16C>T | Intron (SNP) | VAF 121/525 reads (23%) | catalogued as rs1003978651; called by muse, mutect2, varscan2
- AC015911.9 | n.646G>A | RNA (SNP) | VAF 39/227 reads (17%) | catalogued as COSV63138299; called by muse, mutect2, varscan2
- DCHS2 | n.7271T>A | RNA (SNP) | VAF 13/263 reads (5%) | called by muse, mutect2
- FAM86C2P | n.34G>A | RNA (SNP) | VAF 42/305 reads (14%) | catalogued as rs1237818571; called by muse, mutect2, varscan2
- GUSBP10 | n.251C>T | RNA (SNP) | VAF 73/383 reads (19%) | catalogued as rs766815205; called by muse, mutect2, varscan2
- HERC2P4 | n.211T>C | RNA (SNP) | VAF 72/442 reads (16%) | called by muse, mutect2, varscan2
- PIWIL1 | c.2469+11C>G | Intron (SNP) | VAF 12/186 reads (6%) | catalogued as COSV99806801; called by muse, mutect2
